TCGA case TCGA-36-1580 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: BC Cancer Agency. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/533f5ff9-466c-4cdb-9c46-b841c2626775

Demographics
Sex at birth: female; Age at index: 82 years; Vital status: Dead; Days to death: 737 days (2.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 82.1 years (29,992 days); Year of diagnosis: 2007; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 348 days; Number of cycles: 11; Treatment dose: 4,796 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 454 days (1.2 years); Days to treatment end: 553 days (1.5 years); Number of cycles: 4; Treatment dose: 222 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 83.3 years (30,432 days); Days to diagnosis: 440 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 440 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 440 days (1.2 years); Evidence of recurrence type: Physical Examination.
- Days to follow up: 737 days (2.0 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-36-1580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-36-1580-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 45.
  Slide TCGA-36-1580-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
- Sample TCGA-36-1580-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Liposomal Doxorubicin; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 737 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 737 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 440 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-36-1580-01): tumor purity 0.53, ploidy 4.6, whole-genome doublings 2 (call status: legacy_call).
